Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HH, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HH-01A (Primary Tumor).

ICD-O-3
Carcinoma, Squamous Cell
basaloid 8083/3
Site: Lung, lower lobe
C34.3
9/21/13

Synoptic translated report

Site : Left lung inferior lobe

☐ Central ☒ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 1.5 cm (largest diameter)

Visceral pleural invasion: ☐ Yes ☒ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis : Basaloid squamous cell carcinoma

Node status : N0 (0/30)

TNM : pT1 pN0 (0/30) G3 R0

Pathologist signature:

Date:

Criteria	W 1/24/13	Yes	No
Site A discrepancy			✓

Source: NCI Genomic Data Commons file a3ae9bcc-a026-45f4-99c0-d8ce3636680d (TCGA-NC-A5HH.33B3A6BB-14EF-4CCB-B8C3-E4158FBCEA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).